Gene-level copy-number profile of tumor specimen TCGA-13-1506-01A from TCGA case TCGA-13-1506, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.8 years (16,734 days).
Specimen TCGA-13-1506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d846aadd-9cf1-41a8-8fa4-c55b666d0a37.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1506-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3b939366-0bf5-4248-a766-4867238895a2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,338; copy number 2: 12,346; copy number 3: 26,033; copy number 4: 15,326; copy number 5: 1,518; copy number 6: 429; copy number 7: 1,343; copy number 8: 1,329; copy number 9: 101; copy number 10: 42; copy number 14: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1506-01A-01D-0472-01): tumor purity 0.94, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,829 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,269,653–180,909,166, 8 genes, copy number 7 (within-gene range 3–7): ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816.
- chr3:89,283,016–89,314,604, 1 gene, copy number 7: AC109129.1.
- chr3:161,816,909–198,222,513, 646 genes, copy number 7 (broad region; genes not listed).
- chr5:21,616,262–23,305,143, 12 genes, copy number 8: AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3.
- chr5:43,602,692–45,696,498, 18 genes, copy number 7 (within-gene range 4–7): NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1.
- chr11:32,387,775–32,794,658, 11 genes, copy number 7 (within-gene range 3–7): WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73.
- chr11:121,101,243–121,633,763, 8 genes, copy number 7 (within-gene range 3–7): TECTA, AP001124.1, RPS4XP12, SC5D, BMPR1AP2, AP002365.1, AP000977.1, SORL1.
- chr12:66,767–31,591,136, 784 genes, copy number 8–9 (broad region; genes not listed).
- chr12:31,594,093–31,594,206, 1 gene, copy number 8: RNU5F-4P.
- chr12:53,935,328–54,280,133, 37 genes, copy number 7: HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2.
- chr12:54,280,193–54,301,015, 2 genes, copy number 7: HNRNPA1, NFE2.
- chr14:68,421,698–68,685,565, 4 genes, copy number 7: PPIAP6, AL121820.3, AL121820.2, AL121820.1.
- chr17:28,879,335–29,057,216, 12 genes, copy number 7: FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4.
- chr17:29,073,521–29,078,857, 1 gene, copy number 7: TIAF1.
- chr19:9,689,924–24,163,425, 783 genes, copy number 7–10 (within-gene range 1–10) (broad region; genes not listed).
- chr19:29,775,504–40,898,282, 459 genes, copy number 7–14 (within-gene range 5–14) (broad region; genes not listed).
- chr20:61,953,469–62,065,810, 1 gene, copy number 7 (within-gene range 5–7): TAF4.
- chr20:62,037,429–62,776,996, 41 genes, copy number 7: AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659.

Autosomal genes at a single copy (total copy number 1): 1,338. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
